Somatic mutation profile of tumor specimen MMRF_1998_1_BM_CD138pos (aliquot MMRF_1998_1_BM_CD138pos_T1_KBS5U_L07277) from MMRF case MMRF_1998, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,080 days).
Specimen MMRF_1998_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660d70b3-58ff-4840-b0dd-f8b9467a1ef4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1998_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1998_1_PB_Whole_C3_KBS5U_L07278; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6328f9f7-9a40-4578-b631-1a44b8f0edbc

The open-access MAF lists 126 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 39, Silent 15, Intron 12, 5'UTR 6, 5'Flank 3, RNA 2, Frame Shift Del 2, Nonsense Mutation 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 50/51 reads (98%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRINP3 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1213873314; called by muse, mutect2, varscan2
- CCND1 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs753115532; called by muse, mutect2, varscan2
- CLCN7 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325736301, COSV51974540; called by muse, mutect2, varscan2
- DCC | c.4253A>G p.N1418S | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771572900; called by muse, mutect2, varscan2
- DDX60 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1462278659; called by muse, mutect2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- IGKV4-1 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as rs573464044; called by muse, mutect2, varscan2
- IGKV4-1 | c.328G>C p.A110P | Missense Mutation (SNP) | VAF 51/51 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs775181261; called by muse, mutect2, varscan2
- IGLL5 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs550903741, COSV73251065, COSV73251253; called by muse, mutect2, varscan2
- INHA | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs960266462, COSV54719382; called by muse, mutect2, varscan2
- ITGA1 | c.858C>A p.D286E | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50880659; called by muse, mutect2, varscan2
- JPH2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs1389682047; called by muse, mutect2, varscan2
- OR2T11 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 244/366 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1331618307; called by muse, mutect2, varscan2
- OR2Y1 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 110/224 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV57137739; called by muse, mutect2, varscan2
- PTPN14 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 107/160 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs755709746; called by muse, mutect2, varscan2
- RFXAP | c.794A>G p.Q265R | Missense Mutation (SNP) | VAF 41/488 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs755429683; called by muse, mutect2
- ZFHX2 | c.7390G>A p.A2464T | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs1242549228; called by muse, mutect2, varscan2
- ZKSCAN1 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT tolerated (0.69); PolyPhen benign (0.375); catalogued as rs202154703; called by muse, mutect2, varscan2
- ZNF532 | c.2113C>T p.L705F | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as COSV60173214; called by muse, mutect2, varscan2
- ZNF679 | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1346563451; called by muse, mutect2, varscan2
- ABHD13 | c.748T>G p.Y250D | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ALKBH3 | c.386A>C p.Q129P | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- B3GALNT2 | c.1338G>T p.W446C | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLPP | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTSZ | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FHOD3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- HYDIN | c.2309C>T p.T770I | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- IFFO2 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, varscan2
- IRS2 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- KCNMA1 | c.1773A>T p.K591N | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- KDM3B | c.4851T>A p.Y1617* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- LRPPRC | c.1540A>G p.S514G | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MDM2 | c.907A>T p.I303F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MED25 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEDD9 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NF1 | c.1753T>G p.L585V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); called by muse, mutect2
- NUFIP2 | c.1982del p.A661Vfs*23 | Frame Shift Del (DEL) | VAF 63/176 reads (36%) | called by mutect2, pindel, varscan2
- PANK4 | c.907A>C p.I303L | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PM20D2 | c.887C>G p.A296G | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PWWP3B | c.2014T>A p.Y672N | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- RFTN1 | c.569_600del p.A190Gfs*3 | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | called by mutect2, pindel
- SCYL3 | c.2137T>C p.S713P (on ENST00000367770; = p.S659P on NM_020423.7) | Missense Mutation (SNP) | VAF 80/267 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEL1L2 | c.1902G>T p.M634I | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC43A1 | c.1556T>A p.F519Y | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- SMAD5 | c.1068G>C p.Q356H | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- VPS9D1 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- VSTM4 | c.188T>C p.F63S | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ARHGAP21 | c.1971G>A p.Q657= | Silent (SNP) | VAF 58/112 reads (52%) | called by muse, mutect2, varscan2
- CAPN15 | c.774G>A p.P258= | Silent (SNP) | VAF 73/153 reads (48%) | catalogued as rs751303362; called by muse, mutect2, varscan2
- CCSER1 | c.1740A>G p.K580= | Silent (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- CLPP | c.46A>C p.R16= | Silent (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- MCM3AP | c.4482T>A p.P1494= | Silent (SNP) | VAF 78/172 reads (45%) | called by muse, mutect2, varscan2
- MUC3A | c.9108G>A p.P3036= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as rs1465449725; called by muse, mutect2, varscan2
- MYF5 | c.637C>A p.R213= | Silent (SNP) | VAF 87/209 reads (42%) | catalogued as COSV57354477; called by muse, mutect2, varscan2
- MYRIP | c.1254C>A p.P418= | Silent (SNP) | VAF 73/139 reads (53%) | called by muse, mutect2, varscan2
- MYRIP | c.1764C>T p.Y588= | Silent (SNP) | VAF 92/176 reads (52%) | catalogued as rs201459866; called by muse, mutect2, varscan2
- MYT1 | c.435C>T p.P145= | Silent (SNP) | VAF 102/229 reads (45%) | catalogued as rs760676624; called by muse, mutect2, varscan2
- OR5A2 | c.825G>A p.V275= | Silent (SNP) | VAF 96/207 reads (46%) | called by muse, mutect2, varscan2
- PTGIR | c.6G>A p.A2= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs748955635; called by muse, mutect2, varscan2
- TXNDC11 | c.651C>T p.L217= | Silent (SNP) | VAF 120/250 reads (48%) | called by muse, mutect2, varscan2
- USP5 | c.1578G>A p.Q526= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV57540007; called by muse, mutect2
- ZC3H7B | c.2907T>A p.A969= | Silent (SNP) | VAF 61/129 reads (47%) | called by muse, mutect2, varscan2
- ABHD2 | c.*6346C>T | 3'UTR (SNP) | VAF 38/87 reads (44%) | catalogued as rs1027644932; called by muse, mutect2, varscan2
- ACBD6 | c.-114C>T | 5'UTR (SNP) | VAF 41/129 reads (32%) | catalogued as COSV100852384; called by muse, mutect2, varscan2
- ACOT11 | c.*693G>A | 3'UTR (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2
- ADAMTS2 | c.*1187C>A | 3'UTR (SNP) | VAF 69/137 reads (50%) | catalogued as rs1214966466; called by muse, mutect2, varscan2
- ADAMTS4 | c.*535dup | 3'UTR (INS) | VAF 71/207 reads (34%) | called by mutect2, pindel, varscan2
- ADCY2 | c.*613C>A | 3'UTR (SNP) | VAF 74/160 reads (46%) | called by muse, mutect2, varscan2
- ADGRF1 | c.611+644A>T | Intron (SNP) | VAF 153/321 reads (48%) | called by muse, mutect2, varscan2
- ADH1B | c.*1903C>T | 3'UTR (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- AGAP3 | c.598+69G>C | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499854 T>G | 5'Flank (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- ARL5B | c.*3413A>G | 3'UTR (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- ASAH2 | c.*2269C>G | 3'UTR (SNP) | VAF 215/439 reads (49%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.841+276C>G | Intron (SNP) | VAF 41/158 reads (26%) | catalogued as rs986820964; called by muse, mutect2, varscan2
- BCL11A | c.*494T>A | 3'UTR (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2
- C8orf86 | n.715A>G | RNA (SNP) | VAF 50/90 reads (56%) | called by muse, mutect2, varscan2
- CASZ1 | c.-23-392C>T | Intron (SNP) | VAF 47/92 reads (51%) | catalogued as rs1256179972; called by muse, mutect2, varscan2
- CCDC66 | c.710+92T>G | Intron (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- CCND1 | c.*1172T>G | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- CDC7 | c.*817T>C | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- COL18A1 | c.3624+59C>T | Intron (SNP) | VAF 38/78 reads (49%) | catalogued as rs992197790, COSV60589500; called by muse, mutect2, varscan2
- CTC1 | c.1946-15A>G | Intron (SNP) | VAF 5/109 reads (5%) | called by muse, mutect2
- DGKD | c.*238C>T | 3'UTR (SNP) | VAF 77/161 reads (48%) | catalogued as rs772425160; called by muse, mutect2, varscan2
- DGKD | c.*601C>G | 3'UTR (SNP) | VAF 41/105 reads (39%) | called by muse, varscan2
- DGKD | c.*660C>T | 3'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, varscan2
- DGKD | c.*831C>G | 3'UTR (SNP) | VAF 52/107 reads (49%) | called by muse, mutect2, varscan2
- ENO2 | c.-12-116A>C | Intron (SNP) | VAF 9/49 reads (18%) | catalogued as rs1360624833; called by muse, mutect2
- EPHA3 | c.*1291T>G | 3'UTR (SNP) | VAF 55/127 reads (43%) | called by muse, mutect2, varscan2
- FAM107B | c.-81C>T | 5'UTR (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- FAM131A | c.-759C>T | 5'UTR (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- FN3KRP | c.*18A>T | 3'UTR (SNP) | VAF 46/83 reads (55%) | called by muse, mutect2, varscan2
- HACD4 | c.*2067T>G | 3'UTR (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- HSF2 | c.*439T>C | 3'UTR (SNP) | VAF 55/106 reads (52%) | called by muse, mutect2, varscan2
- KIDINS220 | c.108+151T>C | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- KLHL32 | c.*328A>C | 3'UTR (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- LANCL2 | c.-285C>T | 5'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- LRP2BP | c.-112T>C | 5'UTR (SNP) | VAF 179/371 reads (48%) | called by muse, mutect2, varscan2
- MAP3K1 | c.*158A>G | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- MARCHF4 | c.-253G>A | 5'UTR (SNP) | VAF 48/87 reads (55%) | called by muse, mutect2, varscan2
- MIER1 | c.*316A>T | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- MINDY2 | c.*1650G>T | 3'UTR (SNP) | VAF 152/360 reads (42%) | called by mutect2, varscan2
- MIR181A1 | n.60C>G | RNA (SNP) | VAF 92/246 reads (37%) | called by muse, mutect2, varscan2
- NFX1 | c.3039+368C>T | Intron (SNP) | VAF 23/36 reads (64%) | catalogued as rs184490310; called by muse, mutect2, varscan2
- NPNT | c.*1118A>G | 3'UTR (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- NUDT18 | c.*387G>T | 3'UTR (SNP) | VAF 28/51 reads (55%) | catalogued as rs192299592; called by muse, mutect2, varscan2
- PAK1IP1 | c.*178T>A | 3'UTR (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- PCNX1 | chr14:70907449 G>A | 5'Flank (SNP) | VAF 15/31 reads (48%) | catalogued as rs1248167869; called by muse, mutect2, varscan2
- PGAM1 | c.139+1342C>A | Intron (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- PLOD2 | c.*600A>T | 3'UTR (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- RBM20 | c.*2511G>A | 3'UTR (SNP) | VAF 52/89 reads (58%) | catalogued as rs1331401222; called by muse, mutect2, varscan2
- SLC28A1 | c.461+666del | Intron (DEL) | VAF 20/53 reads (38%) | catalogued as rs1450147542; called by mutect2, varscan2
- SLC35D1 | c.*928A>G | 3'UTR (SNP) | VAF 27/55 reads (49%) | catalogued as rs1286350149; called by muse, mutect2, varscan2
- SNORD116-18 | chr15:25090136 T>A | 3'Flank (SNP) | VAF 57/97 reads (59%) | called by muse, mutect2, varscan2
- SPRTN | c.*858T>G | 3'UTR (SNP) | VAF 77/231 reads (33%) | called by muse, mutect2, varscan2
- TAX1BP3 | c.*242C>T | 3'UTR (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- TLE4 | chr9:79571801 G>A | 5'Flank (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- TLL1 | c.*685T>C | 3'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- TMEM132B | c.*4591G>A | 3'UTR (SNP) | VAF 28/77 reads (36%) | catalogued as rs904380350; called by muse, mutect2, varscan2
- TRPC4 | c.*106A>C | 3'UTR (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- TSTD2 | c.*185A>T | 3'UTR (SNP) | VAF 9/226 reads (4%) | called by muse, mutect2
- TUB | c.*1818T>C | 3'UTR (SNP) | VAF 42/83 reads (51%) | called by muse, mutect2, varscan2
- UBE2N | c.*353_*356del | 3'UTR (DEL) | VAF 246/552 reads (45%) | called by mutect2, pindel, varscan2
- UGT8 | c.*1869dup | 3'UTR (INS) | VAF 10/115 reads (9%) | called by pindel, varscan2
- VGLL3 | c.*6052G>T | 3'UTR (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
